Somatic mutation profile of tumor specimen MMRF_2598_1_BM_CD138pos (aliquot MMRF_2598_1_BM_CD138pos_T1_KHS5U_L12852) from MMRF case MMRF_2598, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 82.2 years (30,017 days).
Specimen MMRF_2598_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1e255a33-75d1-4d8f-9132-a13b9ec20431.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2598_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2598_1_PB_Whole_C3_KHS5U_L12853; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e8df7f3-e8c5-48ac-bf2f-c4b81f66e70a

The open-access MAF lists 193 somatic variants for this specimen: 72 protein-altering or splice-affecting, 27 silent, 94 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 61, 3'UTR 50, Intron 27, Silent 27, 5'UTR 8, 3'Flank 5, Frame Shift Ins 4, Frame Shift Del 3, 5'Flank 2, Nonsense Mutation 2, RNA 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 125/592 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSF2 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 31/242 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as rs764566310; called by muse, mutect2, varscan2
- ARHGAP32 | c.4787C>G p.S1596C (on ENST00000310343 / NM_001378025.1; = p.S1247C on NM_014715.4) | Missense Mutation (SNP) | VAF 131/668 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs754890873; called by muse, mutect2, varscan2
- ARHGAP39 | c.2056C>T p.R686C | Missense Mutation (SNP) | VAF 82/155 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.982); catalogued as rs755955179, COSV52776232; called by muse, mutect2, varscan2
- ARL5C | c.457C>T p.H153Y | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.984); catalogued as rs1366680173; called by muse, mutect2, varscan2
- BHLHE22 | c.646G>T p.G216C | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.282); catalogued as rs1232631346; called by muse, mutect2, varscan2
- C1orf167 | c.2554G>C p.D852H | Missense Mutation (SNP) | VAF 63/127 reads (50%) | SIFT tolerated (0.2); PolyPhen benign (0.326); catalogued as rs1293147009; called by muse, mutect2, varscan2
- CNOT3 | c.732dup p.S245Qfs*8 | Frame Shift Ins (INS) | VAF 54/188 reads (29%) | catalogued as rs753475896; called by mutect2, varscan2
- CNTNAP3 | c.1949A>T p.H650L | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV52666933; called by muse, mutect2, varscan2
- CUL3 | c.1526C>T p.T509M | Missense Mutation (SNP) | VAF 62/122 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100024409; called by muse, mutect2, varscan2
- CXCR5 | c.760C>T p.R254W | Missense Mutation (SNP) | VAF 76/449 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs369220984; called by muse, mutect2, varscan2
- DHRS4L2 | c.550G>A p.V184I | Missense Mutation (SNP) | VAF 13/187 reads (7%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.995); catalogued as rs774404113; called by muse, mutect2
- DYSF | c.3022G>A p.D1008N | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs200943384, COSV99246397; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FHOD3 | c.3548C>G p.A1183G (on ENST00000359247 / NM_001281739.3; = p.A1200G on NM_025135.5) | Missense Mutation (SNP) | VAF 46/275 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); catalogued as rs756002908; called by muse, mutect2, varscan2
- IGLV3-1 | c.297G>C p.M99I | Missense Mutation (SNP) | VAF 100/198 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs541687060; called by muse, varscan2
- IGLV3-1 | c.304G>C p.A102P | Missense Mutation (SNP) | VAF 94/200 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs371563415; called by muse, varscan2
- INPP5A | c.734C>T p.T245M | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.916); catalogued as rs1199108796, COSV61248932; called by muse, mutect2, varscan2
- IQCA1 | c.2417C>T p.A806V | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as rs758032787, COSV54502798, COSV99608385; called by muse, mutect2, varscan2
- JUP | c.959G>A p.R320H | Missense Mutation (SNP) | VAF 41/167 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as rs781965392, COSV60279700; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNJ4 | c.392C>T p.T131M | Missense Mutation (SNP) | VAF 165/348 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57856056; called by muse, mutect2, varscan2
- MAMLD1 | c.50T>C p.F17S | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.368); catalogued as COSV53374445; called by muse, mutect2
- MTUS1 | c.2591C>A p.S864* | Nonsense Mutation (SNP) | VAF 27/31 reads (87%) | catalogued as COSV50583165; called by muse, mutect2, varscan2
- MUC12 | c.561C>A p.D187E (on ENST00000379442; = p.D44E on NM_001164462.1) | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.428); catalogued as rs756182682; called by muse, mutect2, varscan2
- NACC2 | c.952G>A p.V318M | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.066); catalogued as rs751580569; called by muse, mutect2, varscan2
- NFIA | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100963337; called by muse, mutect2, varscan2
- OGDHL | c.236A>G p.E79G | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs779252943; called by muse, mutect2, varscan2
- PHLDB2 | c.3332G>A p.R1111H (on ENST00000393925 / NM_001134439.2; = p.R1068H on NM_145753.2) | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs561310661, COSV67308692; called by muse, mutect2, varscan2
- RLBP1 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 215/454 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs772116454; called by muse, mutect2, varscan2
- RRAS2 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 28/235 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0.034); catalogued as rs1386909460; called by muse, mutect2, varscan2
- SEC63 | c.209T>C p.I70T | Missense Mutation (SNP) | VAF 83/163 reads (51%) | SIFT tolerated (0.79); PolyPhen benign (0.001); catalogued as rs1456858377; called by muse, mutect2, varscan2
- SPCS3 | c.156_158del p.E52del | In Frame Del (DEL) | VAF 11/66 reads (17%) | catalogued as rs1560837245; called by pindel, varscan2
- TPSG1 | c.667G>A p.G223R | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.707); catalogued as rs113403420; called by muse, mutect2, varscan2
- TRIM40 | c.73G>A p.V25M | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.488); catalogued as rs775056669, COSV57157860; called by muse, mutect2
- VASH2 | c.908C>T p.P303L (on ENST00000517399 / NM_001301056.2; = p.P259L on NM_024749.5) | Missense Mutation (SNP) | VAF 20/125 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as rs780081188, COSV55119425, COSV99663471; called by muse, mutect2, varscan2
- VIL1 | c.613C>T p.R205C | Missense Mutation (SNP) | VAF 82/170 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs763341658; called by muse, mutect2, varscan2
- ZNF880 | c.1099C>T p.L367F | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs370101970; called by muse, mutect2, varscan2
- ADCY1 | c.2926C>T p.R976* | Nonsense Mutation (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2, varscan2
- CAPN12 | c.1007_1014dup p.S339Rfs*5 | Frame Shift Ins (INS) | VAF 44/258 reads (17%) | called by mutect2, varscan2
- CCDC66 | c.497_503del p.Q166Lfs*6 (on ENST00000394672 / NM_001353147.1; = p.Q132Lfs*6 on NM_001012506.5 and 6 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 30/254 reads (12%) | called by mutect2, pindel, varscan2
- CCDC7 | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- CRTAP | c.470A>G p.K157R | Missense Mutation (SNP) | VAF 23/32 reads (72%) | SIFT tolerated (0.07); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- CTDSP2 | c.704C>G p.S235C | Missense Mutation (SNP) | VAF 65/146 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CTSL | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- DHTKD1 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DUOX1 | c.4245G>C p.K1415N | Missense Mutation (SNP) | VAF 111/937 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- EGFR | c.1679_1698del p.P560Hfs*21 | Frame Shift Del (DEL) | VAF 18/164 reads (11%) | called by mutect2, pindel
- FKBPL | c.379C>A p.L127M | Missense Mutation (SNP) | VAF 25/290 reads (9%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); called by muse, mutect2
- INO80D | c.1980G>C p.Q660H | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- JAK2 | c.936+1G>T p.X312_splice | Splice Site (SNP) | VAF 60/221 reads (27%) | called by muse, mutect2, varscan2
- KANK1 | c.1325_1326del p.E442Gfs*8 | Frame Shift Del (DEL) | VAF 52/238 reads (22%) | called by pindel, varscan2
- KIF12 | c.1634C>A p.S545Y (on ENST00000640217; = p.S407Y on NM_138424.1) | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- KRTAP1-5 | c.167G>T p.C56F | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, varscan2
- MKI67 | c.1893C>G p.I631M | Missense Mutation (SNP) | VAF 67/208 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- MYO5A | c.4126G>A p.E1376K | Missense Mutation (SNP) | VAF 43/317 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- OR4C12 | c.315dup p.G106Wfs*4 | Frame Shift Ins (INS) | VAF 56/214 reads (26%) | called by mutect2, pindel, varscan2
- PADI6 | c.106G>T p.D36Y | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- PCSK5 | c.4109C>T p.P1370L | Missense Mutation (SNP) | VAF 12/288 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.02); called by muse, mutect2
- PDGFRA | c.208G>C p.E70Q | Missense Mutation (SNP) | VAF 35/174 reads (20%) | SIFT tolerated (0.51); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- PLCH2 | c.514C>A p.Q172K | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2
- PLPPR3 | c.820G>A p.A274T (on ENST00000520876 / NM_001270366.2; = p.A302T on NM_024888.2) | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POLR2B | c.2978A>C p.K993T | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- PRSS2 | c.695T>C p.V232A | Missense Mutation (SNP) | VAF 59/683 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RPTOR | c.1794C>A p.D598E | Missense Mutation (SNP) | VAF 45/144 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SATB1 | c.493A>C p.T165P | Missense Mutation (SNP) | VAF 69/472 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC5A7 | c.287T>A p.I96N | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2
- SOCS5 | c.1535A>C p.D512A | Missense Mutation (SNP) | VAF 6/186 reads (3%) | SIFT tolerated (0.38); PolyPhen benign (0.18); called by muse, mutect2
- SOWAHC | c.426dup p.A143Rfs*65 | Frame Shift Ins (INS) | VAF 4/12 reads (33%) | called by mutect2, varscan2
- TENT5C | c.220T>C p.S74P | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- TOR1AIP1 | c.230A>C p.E77A | Missense Mutation (SNP) | VAF 75/188 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.084); called by muse, varscan2
- TOR1AIP1 | c.304A>C p.S102R | Missense Mutation (SNP) | VAF 120/236 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.022); called by muse, varscan2
- TRPC1 | c.2009G>A p.S670N (on ENST00000476941 / NM_001251845.2; = p.S636N on NM_003304.4) | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2
- ZGLP1 | c.698G>A p.R233K | Missense Mutation (SNP) | VAF 101/383 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AIG1 | c.669T>C p.D223= | Silent (SNP) | VAF 86/170 reads (51%) | called by muse, mutect2, varscan2
- ANKRD28 | c.1791A>G p.E597= | Silent (SNP) | VAF 83/293 reads (28%) | called by muse, mutect2, varscan2
- CACNA1B | c.5706G>A p.P1902= | Silent (SNP) | VAF 20/100 reads (20%) | catalogued as rs138511879; called by muse, mutect2, varscan2
- CENPK | c.15T>C p.D5= | Silent (SNP) | VAF 43/405 reads (11%) | called by muse, mutect2, varscan2
- CRB2 | c.2574G>A p.T858= | Silent (SNP) | VAF 54/178 reads (30%) | catalogued as rs756722269, COSV63503359; called by muse, mutect2, varscan2
- CRMP1 | c.183C>T p.N61= | Silent (SNP) | VAF 113/226 reads (50%) | catalogued as rs752770907, COSV61481635; called by muse, mutect2, varscan2
- FBF1 | c.3093G>A p.L1031= (on ENST00000586717; = p.L1046= on NM_001319193.1) | Silent (SNP) | VAF 44/187 reads (24%) | catalogued as rs779415551; called by muse, mutect2, varscan2
- GFM1 | c.1470G>A p.E490= | Silent (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
- IGKV2D-24 | c.171C>T p.Y57= | Silent (SNP) | VAF 124/433 reads (29%) | called by muse, mutect2, varscan2
- KLHL22 | c.870A>G p.Q290= | Silent (SNP) | VAF 50/187 reads (27%) | catalogued as rs773325571; called by muse, mutect2, varscan2
- LILRA4 | c.1497C>T p.I499= | Silent (SNP) | VAF 32/1163 reads (3%) | catalogued as COSV52494633; called by muse, mutect2
- LIPK | c.1029C>T p.D343= | Silent (SNP) | VAF 39/90 reads (43%) | called by muse, mutect2, varscan2
- LLPH | c.156A>G p.V52= | Silent (SNP) | VAF 40/92 reads (43%) | catalogued as COSV99874546; called by muse, mutect2, varscan2
- MRPS6 | c.126G>A p.L42= | Silent (SNP) | VAF 8/142 reads (6%) | called by muse, mutect2
- NT5DC2 | c.921G>T p.R307= | Silent (SNP) | VAF 46/285 reads (16%) | catalogued as rs936541511; called by muse, mutect2, varscan2
- OR5F1 | c.612T>A p.G204= | Silent (SNP) | VAF 65/250 reads (26%) | catalogued as COSV53545265; called by muse, mutect2, varscan2
- OR5L1 | c.582G>A p.V194= | Silent (SNP) | VAF 44/242 reads (18%) | catalogued as rs867934874; called by muse, mutect2, varscan2
- PHLPP1 | c.3630C>T p.D1210= | Silent (SNP) | VAF 7/60 reads (12%) | catalogued as rs367669597; called by muse, mutect2
- PIKFYVE | c.3429C>T p.G1143= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as rs750656442; called by muse, mutect2, varscan2
- RASD2 | c.453G>A p.V151= | Silent (SNP) | VAF 63/192 reads (33%) | called by muse, mutect2, varscan2
- SLC22A12 | c.99C>T p.T33= | Silent (SNP) | VAF 87/291 reads (30%) | called by muse, mutect2, varscan2
- TACC2 | c.4242G>A p.K1414= | Silent (SNP) | VAF 83/152 reads (55%) | called by muse, mutect2, varscan2
- TAMM41 | c.1242A>C p.I414= | Silent (SNP) | VAF 43/193 reads (22%) | called by muse, mutect2, varscan2
- THBD | c.1668C>T p.A556= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as rs1416721648; called by muse, mutect2, varscan2
- TNRC6A | c.4101T>C p.P1367= | Silent (SNP) | VAF 150/307 reads (49%) | called by muse, mutect2, varscan2
- USP8 | c.2889A>G p.T963= | Silent (SNP) | VAF 11/72 reads (15%) | catalogued as rs770305140; called by muse, mutect2, varscan2
- WDHD1 | c.1167A>G p.L389= | Silent (SNP) | VAF 31/302 reads (10%) | called by muse, mutect2, varscan2
- AACS | c.1424-68G>A | Intron (SNP) | VAF 18/64 reads (28%) | called by muse, mutect2, varscan2
- ABCA13 | c.*685A>C | 3'UTR (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.4284+2168C>T | Intron (SNP) | VAF 26/26 reads (100%) | catalogued as rs1224183437; called by muse, mutect2, varscan2
- ADAMTS8 | c.-180G>A | 5'UTR (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- ANKRD42 | c.502+1870T>C | Intron (SNP) | VAF 180/494 reads (36%) | called by muse, mutect2, varscan2
- ANOS1 | c.*3711C>T | 3'UTR (SNP) | VAF 71/76 reads (93%) | catalogued as rs1020508868; called by muse, mutect2, varscan2
- ARFIP2 | c.99+107_99+110del | Intron (DEL) | VAF 29/90 reads (32%) | catalogued as rs1237639046; called by mutect2, pindel, varscan2
- ARGLU1 | c.-142G>A | 5'UTR (SNP) | VAF 16/150 reads (11%) | called by muse, mutect2, varscan2
- ARID2 | c.*2428T>G | 3'UTR (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2, varscan2
- BMP6 | c.*234T>A | 3'UTR (SNP) | VAF 21/89 reads (24%) | called by muse, mutect2, varscan2
- BMPR1B | chr4:95156067 T>A | 3'Flank (SNP) | VAF 27/104 reads (26%) | called by muse, mutect2, varscan2
- BRICD5 | chr16:2211309 G>T | 5'Flank (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- C1orf21 | c.*5240C>T | 3'UTR (SNP) | VAF 13/48 reads (27%) | catalogued as rs569750805; called by muse, mutect2, varscan2
- CABP1 | c.686-65C>T | Intron (SNP) | VAF 6/132 reads (5%) | called by muse, mutect2
- CACUL1 | c.*4162A>T | 3'UTR (SNP) | VAF 6/86 reads (7%) | called by muse, mutect2
- CADM2 | chr3:86067319 ins A | 3'Flank (INS) | VAF 48/74 reads (65%) | catalogued as rs1021340313; called by mutect2, varscan2
- CALCRL | c.*613T>A | 3'UTR (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- CARD8 | c.*491T>C | 3'UTR (SNP) | VAF 13/62 reads (21%) | called by mutect2, varscan2
- CBX1 | c.*436dup | 3'UTR (INS) | VAF 148/381 reads (39%) | called by mutect2, pindel, varscan2
- CCNDBP1 | c.331+68T>G | Intron (SNP) | VAF 35/114 reads (31%) | called by muse, mutect2, varscan2
- CD151 | c.276+42G>C | Intron (SNP) | VAF 33/99 reads (33%) | called by muse, mutect2, varscan2
- CEACAM3 | c.543-233C>T | Intron (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2
- CEP162 | c.*369G>C | 3'UTR (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- CLEC4E | c.*296C>T | 3'UTR (SNP) | VAF 6/45 reads (13%) | catalogued as rs1049340625; called by muse, mutect2, varscan2
- CPNE4 | c.*992C>T | 3'UTR (SNP) | VAF 42/113 reads (37%) | catalogued as rs572484878; called by muse, mutect2, varscan2
- CST8 | c.*44C>A | 3'UTR (SNP) | VAF 86/383 reads (22%) | catalogued as COSV99850029; called by muse, mutect2, varscan2
- CTDSP2 | c.*506C>G | 3'UTR (SNP) | VAF 9/37 reads (24%) | called by muse, varscan2
- CTDSP2 | c.*424C>T | 3'UTR (SNP) | VAF 32/76 reads (42%) | catalogued as rs1430386756; called by muse, varscan2
- CTDSP2 | c.412-330C>G | Intron (SNP) | VAF 18/50 reads (36%) | called by muse, varscan2
- CTSL | c.*42G>A | 3'UTR (SNP) | VAF 84/329 reads (26%) | catalogued as rs759796746, COSV100446735; called by muse, mutect2, varscan2
- CYP4F12 | c.525+101A>C | Intron (SNP) | VAF 9/74 reads (12%) | called by muse, mutect2
- DCDC2 | c.*1003G>C | 3'UTR (SNP) | VAF 8/149 reads (5%) | called by muse, mutect2
- DNAJA2 | c.*576_*583del | 3'UTR (DEL) | VAF 10/56 reads (18%) | called by pindel, varscan2
- DNASE1L3 | c.*210C>G | 3'UTR (SNP) | VAF 13/65 reads (20%) | called by muse, mutect2, varscan2
- DOLPP1 | c.*1156C>T | 3'UTR (SNP) | VAF 13/251 reads (5%) | called by muse, mutect2
- ETFB | c.58-46T>C | Intron (SNP) | VAF 23/162 reads (14%) | catalogued as rs765125722; called by muse, mutect2, varscan2
- FBXO24 | c.-119C>T | 5'UTR (SNP) | VAF 41/164 reads (25%) | called by muse, mutect2, varscan2
- FGF2 | c.*1235G>A | 3'UTR (SNP) | VAF 18/38 reads (47%) | catalogued as rs752617826, COSV52648166; called by muse, mutect2, varscan2
- FOXL2NB | c.*718A>T | 3'UTR (SNP) | VAF 31/164 reads (19%) | called by muse, mutect2, varscan2
- FSTL1 | c.*1022G>C | 3'UTR (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- GABRA1 | chr5:161898265 A>G | 3'Flank (SNP) | VAF 20/81 reads (25%) | called by muse, mutect2, varscan2
- GFUS | c.147-101A>G | Intron (SNP) | VAF 23/117 reads (20%) | called by muse, mutect2, varscan2
- GLRX | chr5:95823981 C>T | 5'Flank (SNP) | VAF 26/113 reads (23%) | catalogued as rs1159654775; called by muse, mutect2, varscan2
- GPR61 | chr1:109545922 G>C | 3'Flank (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- GPX1 | c.252+122C>T | Intron (SNP) | VAF 111/345 reads (32%) | called by muse, mutect2, varscan2
- H2AC6 | c.-38C>T | 5'UTR (SNP) | VAF 89/172 reads (52%) | catalogued as rs368501447; called by muse, mutect2, varscan2
- HERC4 | c.387-1563C>G | Intron (SNP) | VAF 31/60 reads (52%) | called by muse, mutect2, varscan2
- HOMER1 | c.-422T>C | 5'UTR (SNP) | VAF 14/158 reads (9%) | called by muse, mutect2
- LAMP2 | c.*342T>C | 3'UTR (SNP) | VAF 43/49 reads (88%) | catalogued as rs1375007847; called by muse, mutect2, varscan2
- LARP1B | c.988+121A>G | Intron (SNP) | VAF 87/189 reads (46%) | called by muse, mutect2, varscan2
- LDB2 | c.-27T>C | 5'UTR (SNP) | VAF 63/424 reads (15%) | catalogued as rs1315678136; called by muse, mutect2, varscan2
- LGALS8 | chr1:236551274 C>T | 3'Flank (SNP) | VAF 24/178 reads (13%) | called by muse, mutect2, varscan2
- LRP2 | c.*473_*476del | 3'UTR (DEL) | VAF 7/62 reads (11%) | called by mutect2, pindel, varscan2
- MAF | c.*4141_*4144del | 3'UTR (DEL) | VAF 15/140 reads (11%) | called by mutect2, pindel
- MAPRE2 | c.*2716A>G | 3'UTR (SNP) | VAF 4/48 reads (8%) | catalogued as rs1024919932; called by muse, mutect2
- MED17 | c.775-18G>C | Intron (SNP) | VAF 54/191 reads (28%) | catalogued as COSV52603190; called by muse, mutect2, varscan2
- METTL26 | c.360+126G>A | Intron (SNP) | VAF 22/58 reads (38%) | catalogued as rs913582528; called by muse, varscan2
- MFSD4B | c.*3626T>G | 3'UTR (SNP) | VAF 34/82 reads (41%) | called by muse, mutect2, varscan2
- MIER1 | c.*2012T>G | 3'UTR (SNP) | VAF 48/89 reads (54%) | called by muse, mutect2, varscan2
- MIR600 | chr9:123111629 del CACAGCACGTGACTTGCTGT | RNA (DEL) | VAF 15/76 reads (20%) | called by mutect2, pindel, varscan2
- NABP1 | c.*2003A>G | 3'UTR (SNP) | VAF 24/53 reads (45%) | called by muse, mutect2, varscan2
- NACC2 | c.*3294C>A | 3'UTR (SNP) | VAF 55/282 reads (20%) | called by muse, mutect2, varscan2
- NAMPTP1 | n.341C>A | RNA (SNP) | VAF 77/309 reads (25%) | called by muse, mutect2, varscan2
- NCBP2 | c.*618A>G | 3'UTR (SNP) | VAF 14/83 reads (17%) | called by muse, mutect2, varscan2
- NIPAL1 | c.*2315dup | 3'UTR (INS) | VAF 39/103 reads (38%) | catalogued as rs1465260246; called by mutect2, pindel, varscan2
- NIPSNAP2 | c.*48dup | 3'UTR (INS) | VAF 154/435 reads (35%) | called by mutect2, pindel, varscan2
- NTRK2 | c.1585+8718C>T | Intron (SNP) | VAF 15/100 reads (15%) | called by muse, mutect2, varscan2
- PDGFRA | c.2323+1103G>A | Intron (SNP) | VAF 12/64 reads (19%) | catalogued as rs1445390541; called by muse, mutect2, varscan2
- PIKFYVE | c.*2582T>C | 3'UTR (SNP) | VAF 37/96 reads (39%) | catalogued as rs1007704353; called by muse, mutect2, varscan2
- PPP1R16B | c.*289T>C | 3'UTR (SNP) | VAF 29/91 reads (32%) | called by muse, mutect2, varscan2
- PRKACB | c.*1853dup | 3'UTR (INS) | VAF 56/111 reads (50%) | catalogued as rs1414795616; called by mutect2, varscan2
- RAD1 | c.199-441G>C | Intron (SNP) | VAF 55/207 reads (27%) | called by muse, mutect2, varscan2
- RBM19 | c.-92G>T | 5'UTR (SNP) | VAF 44/184 reads (24%) | called by muse, mutect2, varscan2
- RBM5 | c.483+397C>G | Intron (SNP) | VAF 15/60 reads (25%) | called by muse, mutect2, varscan2
- RPS27A | c.-18+14C>T | Intron (SNP) | VAF 127/239 reads (53%) | called by muse, mutect2, varscan2
- SASH1 | c.*732T>C | 3'UTR (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- SEL1L | c.891+113A>G | Intron (SNP) | VAF 22/39 reads (56%) | called by muse, mutect2, varscan2
- SERBP1 | c.996+34C>G | Intron (SNP) | VAF 71/155 reads (46%) | called by muse, mutect2, varscan2
- SGTB | c.*643T>C | 3'UTR (SNP) | VAF 70/148 reads (47%) | called by muse, mutect2, varscan2
- SLC12A6 | c.2267+37T>G | Intron (SNP) | VAF 54/258 reads (21%) | called by muse, mutect2, varscan2
- SOX2 | c.*857C>A | 3'UTR (SNP) | VAF 35/58 reads (60%) | catalogued as rs1295773622, COSV100327262; called by muse, mutect2, varscan2
- SSR3 | c.*2201_*2204del | 3'UTR (DEL) | VAF 25/90 reads (28%) | called by mutect2, pindel, varscan2
- SYNPO2L | c.*1109G>C | 3'UTR (SNP) | VAF 36/107 reads (34%) | called by muse, mutect2, varscan2
- TERB2 | c.*303C>T | 3'UTR (SNP) | VAF 28/245 reads (11%) | called by muse, mutect2, varscan2
- THBS1 | c.*997T>A | 3'UTR (SNP) | VAF 30/120 reads (25%) | catalogued as rs544819845; called by muse, mutect2, varscan2
- UHRF1BP1 | c.*543A>T | 3'UTR (SNP) | VAF 6/108 reads (6%) | called by muse, mutect2
- USP39 | c.*396G>A | 3'UTR (SNP) | VAF 41/87 reads (47%) | called by muse, mutect2, varscan2
- WDR72 | c.*2810G>A | 3'UTR (SNP) | VAF 16/146 reads (11%) | catalogued as rs1029254751; called by muse, mutect2
- WT1 | c.*354G>A | 3'UTR (SNP) | VAF 40/146 reads (27%) | called by muse, mutect2, varscan2
- ZBTB21 | c.*1541dup | 3'UTR (INS) | VAF 18/114 reads (16%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.3325+3729C>T | Intron (SNP) | VAF 56/159 reads (35%) | catalogued as rs544633028; called by muse, mutect2, varscan2
- ZFP36L2 | c.*1352C>T | 3'UTR (SNP) | VAF 48/91 reads (53%) | called by muse, mutect2, varscan2
- ZFR | c.-32_-31del | 5'UTR (DEL) | VAF 38/234 reads (16%) | called by pindel, varscan2
- ZNF451 | c.186+9742T>A | Intron (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
